Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29B, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29B-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

IS

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Palpable nodule left thigh positive on PET scan. PHx of metastatic melanoma.
Excision of nodule left thigh. A section of nodule has been taken for tumour banking.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"LEFT THIGH". An ellipse of skin, 35 x 7mm to a depth of 25mm. Cut surfaces shows a brown nodule, 25 x 10 x 10mm, present in the subcutis.
One representative section of the nodule in block 1A showing the closest margin.

MICROSCOPIC REPORT

"LEFT THIGH".

The sections show a subcutaneous deposit of malignant melanoma consisting of epithelioid cells. Frequent mitotic figures, up to 21/mm², are present. No necrosis is seen. The lines of resection appear clear of the tumour in the plane of sectioning. The overlying epidermis and dermis show no significant abnormality.

SUMMARY

LEFT THIGH SUBCUTANEOUS TISSUE:
- Consistent with malignant melanoma.

REPORTED BY: Prof.

ICD-0-3

Melanoma, NOS 8720/3

Site: skin, thigh C44.7

hw

6/2/11

A Unit o

Printed

Page 1 of 1

Source: NCI Genomic Data Commons file ad617220-6574-4a2b-8cfa-a07fc6beebdc (TCGA-EE-A29B.7D858F97-4834-40FF-99EE-D01385FA0479.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).